MMRF case MMRF_2021 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/380672b8-7ba4-4427-9252-7404b9e6b6dc

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.3 years (24,206 days); ISS stage: I; Days to last known disease status: 973 days (2.7 years); Days to last follow up: 973 days (2.7 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 144 days; Days to treatment end: 145 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 146 days; Days to treatment end: 146 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 336 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 252 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 252 days; Days to treatment end: 336 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 336 days; Days to treatment end: 449 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 336 days; Days to treatment end: 687 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 336 days; Days to treatment end: 354 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 364 days; Days to treatment end: 434 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 434 days (1.2 years); Days to treatment end: 450 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 462 days (1.3 years); Days to treatment end: 504 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 504 days (1.4 years); Days to treatment end: 505 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 529 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -21 (ECOG 0): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 52.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.152 mg/dL; Immunoglobulin G 40.5 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 9 g/dL; Glucose 6.16 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 84 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 6.9 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 8.31 mmol/L.
- Day 167 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.984 mg/dL; Immunoglobulin G 7.15 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 6.58 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 7.69 ×10⁹/L; Platelets 372 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 6.82 mmol/L.
- Day 252 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0276 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.188 mg/dL; Immunoglobulin G 3.6 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.68 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 4.57 mmol/L.
- Day 336 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.692 mg/dL; Immunoglobulin G 2.58 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.98 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.59 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Albumin 39 g/L; Total Protein 5.5 g/dL; Glucose 5.34 mmol/L.
- Day 434 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.798 mg/dL; Immunoglobulin G 2.11 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 5.73 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.49 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 7.32 mmol/L.
- Day 532 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.679 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 3.28 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 5.67 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.5 mmol/L.
- Day 630 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.145 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.0304 mg/dL; Immunoglobulin G 7.2 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 5.78 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 5.42 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 7.37 mmol/L.
- Day 700: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0312 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.204 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 5.47 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.34 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 7.21 mmol/L.
- Day 812 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.802 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.539 mg/dL; Immunoglobulin G 2.26 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 4.38 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.18 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 6.33 mmol/L.
- Day 896 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.803 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.524 mg/dL; Immunoglobulin G 3.01 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 7.27 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 5.45 mmol/L.
- Day 973 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.969 mg/dL; Immunoglobulin G 7.15 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 5.5 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -21: Weight: 103 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2021_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
- Sample MMRF_2021_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -21 days.
